Gene-level copy-number profile of tumor specimen C3L-03962-03 from CPTAC case C3L-03962, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.7 years (23,986 days).
Specimen C3L-03962-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09e9f4c9-fcff-4508-8870-2c2eb33cc6e8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03962-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,754 have no estimate.
https://portal.gdc.cancer.gov/files/b43fd900-803a-4fa6-b182-29a4cb7c003b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 540; copy number 1: 24,221; copy number 2: 31,044; copy number 3: 1,630; copy number 4: 828; copy number 5: 552; copy number 6: 40; copy number 7: 7; copy number 18: 7.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–1): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:177,430,774–177,442,437, 1 gene: AGA.
- chr4:177,457,111–177,457,228, 1 gene (within-gene range 0–1): RNA5SP172.
- chr8:12,115,767–12,177,550, 6 genes: FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr16:35,021,749–35,085,060, 5 genes (within-gene range 0–1): AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 606 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 7 genes, copy number 18: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr1:153,297,862–153,460,651, 12 genes, copy number 5–6: PGLYRP3, PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7.
- chr3:140,865,075–175,810,548, 501 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:175,473,919–175,477,602, 1 gene, copy number 5: AC008180.3.
- chr3:189,631,389–189,897,276, 3 genes, copy number 5: TP63, AC078809.1, MIR944.
- chr6:52,805,613–52,909,698, 5 genes, copy number 6: GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3.
- chr6:52,977,948–53,236,297, 15 genes, copy number 5: GSTA4, 7SK, RN7SK, CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20.
- chr6:134,343,307–134,520,585, 3 genes, copy number 6–7: LINC01010, CHCHD2P4, CT69.
- chr6:134,960,378–135,260,933, 7 genes, copy number 5–6: HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1.
- chr9:32,783,540–33,282,070, 17 genes, copy number 6: TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5.
- chr13:73,054,976–73,227,260, 5 genes, copy number 7: KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8.
- chr16:32,877,469–32,903,894, 3 genes, copy number 5: SLC6A10P, AC142086.1, IGHV3OR16-15.
- chr17:43,338,741–43,476,665, 11 genes, copy number 5–6: LINC00910, AC109326.1, RNU2-4P, RNU6-1137P, ARL4D, RNU6-470P, MIR2117HG, MIR2117, RNU6-406P, RNU6-971P, AC087650.1.
- chr17:55,264,960–56,595,611, 16 genes, copy number 5: HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG.

Autosomal genes at a single copy (total copy number 1): 22,227. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
